Gene-level copy-number profile of tumor specimen TCGA-ZJ-AAXU-01A from TCGA case TCGA-ZJ-AAXU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.4 years (18,773 days).
Specimen TCGA-ZJ-AAXU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.bf0a2898-3572-4726-aeb0-b20f0d81bb9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-AAXU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a24d6718-469e-4055-8c46-aa1eadf90b66

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,798; copy number 2: 47,785; copy number 3: 6,060; copy number 4: 1,731; copy number 5: 393; copy number 6: 24; copy number 8: 3; copy number 9: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-AAXU-01A-11D-A42N-01): tumor purity 0.54, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 440 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,425,850–172,711,218, 8 genes, copy number 6 (within-gene range 4–6): BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2.
- chr5:34,164,698–35,048,135, 15 genes, copy number 6 (within-gene range 4–6): AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2.
- chr5:35,081,223–35,081,992, 1 gene, copy number 6: AC010368.1.
- chr5:126,360,132–126,509,021, 3 genes, copy number 8: GRAMD2B, AC093535.1, AC093535.2.
- chr8:127,400,399–127,402,150, 1 gene, copy number 5: CCAT2.
- chr8:133,392,211–133,409,107, 2 genes, copy number 5: AF186190.1, ST13P6.
- chr12:66,767–10,810,168, 402 genes, copy number 5–9 (broad region; genes not listed).
- chr12:10,825,317–10,849,475, 3 genes, copy number 9: TAS2R10, AC006518.1, PRR4.
- chr12:10,894,943–10,934,845, 3 genes, copy number 9: AC006518.2, TAS2R13, PRH2.
- chr12:10,964,425–10,986,912, 2 genes, copy number 9: TAS2R15P, TAS2R50.

Autosomal genes at a single copy (total copy number 1): 3,785. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
